Gene-level copy-number profile of tumor specimen TCGA-LN-A5U7-01A from TCGA case TCGA-LN-A5U7, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 46.3 years (16,928 days).
Specimen TCGA-LN-A5U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.22b6f3ff-ae73-43d5-8750-c27a584bc57d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A5U7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb6b5afc-797f-4f4a-bbc9-f13d43bf3f72

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,690; copy number 2: 16,559; copy number 3: 22,664; copy number 4: 13,845; copy number 5: 3,113; copy number 6: 596; copy number 7: 961; copy number 8: 241; copy number 9: 26; copy number 12: 48; copy number 13: 1; copy number 20: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A5U7-01A-11D-A31T-01): tumor purity 0.77, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–62,297,609, 3 genes (within-gene range 0–2): PTPRG, Y_RNA, RPL10AP6.
- chr5:54,048,007–54,075,583, 2 genes: RN7SL801P, AC016601.1.
- chr5:108,747,841–109,196,841, 1 gene (within-gene range 0–3): FER.
- chr5:108,818,041–109,014,940, 4 genes: AC008871.1, Y_RNA, AC109481.1, RNU6-47P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,335 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,419,850–121,580,524, 34 genes, copy number 7: NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr3:138,889,255–188,147,310, 816 genes, copy number 7 (broad region; genes not listed).
- chr3:188,153,284–188,890,671, 1 gene, copy number 9 (within-gene range 5–9): LPP.
- chr3:188,562,238–198,222,513, 219 genes, copy number 8–9 (broad region; genes not listed).
- chr5:18,236,123–18,547,605, 2 genes, copy number 7: SNORD81, RN7SL58P.
- chr6:20,534,457–22,675,493, 21 genes, copy number 8–13 (within-gene range 2–13): CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2.
- chr6:92,887,251–92,888,581, 1 gene, copy number 12: ATF1P1.
- chr11:68,903,863–71,252,577, 58 genes, copy number 20 (within-gene range 2–20): IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664.
- chr13:54,115,783–54,441,315, 4 genes, copy number 8: LINC00458, AL356052.1, MIR1297, RPL13AP25.
- chr13:68,861,284–78,910,542, 117 genes, copy number 7–9 (broad region; genes not listed).
- chr18:43,115,747–47,251,660, 62 genes, copy number 8–12 (within-gene range 2–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
